Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GU, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GU-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

CASE NUMBER:

DIAGNOSIS:

Final Results

Final

1. Adrenal gland, right (adrenalectomy):
- Pheochromocytoma; see note.

2. Adrenal gland, left (adrenalectomy):
- Pheochromocytoma; see note.

NOTE: Immunohistochemistry is performed on blocks 1A and 2A. The tumor cells stain positive for NSE, Synaptophysin, Chromogranin, and CD56; lesional tumor cells stain negative for Inhibin. S100 highlights the sustentacular cells.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the

they have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief

Clinical History: male

patient with history of bilateral carotid globus
tumors and bilateral

pheochromocytoma Specimen Taken For Protocol:

- Yes

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative
Diagnosis:

same Operative Findings: large masses bilateral adrenal
glands

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

2. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh from OR labeled with the patient's name, medical record number, are two containers further described as follows:

1. "Right adrenal gland". The specimen consists of a single soft tissue mass with attached fibroadipose tissue measuring overall 10.5 x 3.2 x 3.4 cm, weighing 64.36 grams. It is inked black and bivalved to reveal tumor measuring 2.7 x 2.4 cm with gray/red brown cut surface and a portion of normal adrenal gland measuring 2.4 x 1.2 cm in diameter. Approximately 3.4 x 1.4 x 1.6 cm piece from the tumor and approximately 2.0 x 0.6 x 0.4 cm normal tissue were procured for Dr. approximately 0.8 x 0.4 x 0.4 cm normal tissue was procured for tissue bank. The procurement was performed by
n Frozen Room. Received in Surgical Pathology, the specimen is

Requested By:

Do not file in Medical Record

[page 2 of 2]
consistent with the above description. Representative sections are submitted in white cassettes labeled for serial sectioning.

1A-1F: Tumor

1G, 1H: Normal-appearing adrenal gland

2. "Left adrenal gland". The specimen consists of a soft tissue mass measuring 7.5 x 5.2 x 3.6 cm, weighing 54.75 grams. The specimen is inked black and bivalved revealing a tumor mass measuring 3.4 x 2.3 cm in diameter with a portion of normal adrenal gland measuring 1.2 x 1.2 x 1.3 cm. The cut surface is red/green, variegated. Approximately 1.4 x 1.4 x 0.9 cm tissue fragment in aggregate from the tumor, and approximately 1.8 x 0.6 x 0.4 cm of normal adrenal gland were procured Dr. Approximately 1.8 x 0.6 x 0.4 cm normal adrenal gland was procured for tissue bank. The procurement was performed by Dr. Frozen Room. Received in Surgical Pathology, the specimen is consistent with the above description. Representative sections are submitted in white cassettes labeled serial sectioning.

No consultants

#

#

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 15e1dab5-3437-4da9-8a9e-775939e251ed (TCGA-QR-A6GU.A1824EB7-6228-42BC-869C-AD3BD3B52129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).